Gene-level copy-number profile of tumor specimen ALCH-B1V0-TTP1-A from ALCHEMIST case ALCH-B1V0, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 81.2 years (29,645 days).
Specimen ALCH-B1V0-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1cc90d2d-a5e4-49de-ac7c-3721608168b8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1V0-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,744 have no estimate.
https://portal.gdc.cancer.gov/files/b2711753-3c6e-4714-8290-5a3f090b6230

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 4,288; copy number 2: 48,189; copy number 3: 5,033; copy number 4: 1,346; copy number 5: 2; copy number 10: 3; copy number 20: 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:31,784,779–31,817,961, 1 gene (within-gene range 0–2): PAX6.
- chr13:100,062,296–100,063,601, 1 gene: ASNSP3.
- chr15:65,381,484–65,422,947, 1 gene: IGDCC4.
- chr22:17,329,034–17,329,232, 1 gene: CECR9.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:86,649–126,123, 3 genes, copy number 10: OR4F2P, AC069287.1, CICP23.
- chr21:44,133,610–44,210,114, 1 gene, copy number 20 (within-gene range 2–20): GATD3A.
- chr21:44,172,169–44,194,338, 2 genes, copy number 5: AP001056.2, AP001056.1.

Autosomal genes at a single copy (total copy number 1): 1,958. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
